CCDI case PBCMMV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/a616c5e4-8ea2-4c57-95ab-6bb6995c52a3

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,664 days).

Biospecimens (3 samples)
- Sample 0DW2VK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW2VP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW2WF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
